Somatic mutation profile of tumor specimen TCGA-ZP-A9D4-01A (aliquot TCGA-ZP-A9D4-01A-11D-A36X-10) from TCGA case TCGA-ZP-A9D4, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G1; Age at diagnosis: 64.8 years (23,656 days).
Specimen TCGA-ZP-A9D4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d7a6a16-f2a7-4039-924c-5277b14243c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZP-A9D4-10A (Blood Derived Normal), aliquot TCGA-ZP-A9D4-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89764dae-8074-458a-8423-4c1ce40879d6

The open-access MAF lists 70 somatic variants for this specimen: 52 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 16, Splice Region 2, Nonsense Mutation 2, Splice Site 2, Intron 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.104T>G p.I35S | Missense Mutation (SNP) | VAF 47/117 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62687967, COSV62691314, COSV62693017; called by muse, mutect2, varscan2
- ACTC1 | c.527C>A p.A176D | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99291606; called by muse, mutect2, varscan2
- ALB | c.610C>A p.P204T | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99890779; called by muse, mutect2, varscan2
- ANKMY1 | c.2616G>C p.G872= | Splice Region (SNP) | VAF 15/63 reads (24%) | catalogued as COSV99801377; called by muse, mutect2, varscan2
- BRINP1 | c.2051G>A p.G684D | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56295176, COSV56315791; called by muse, mutect2
- CFAP45 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs779458678, COSV100928464; called by muse, mutect2, varscan2
- CLSTN3 | c.1385A>G p.Y462C | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99866571; called by muse, mutect2, varscan2
- DDX60 | c.1103A>G p.N368S | Missense Mutation (SNP) | VAF 242/636 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV101190262; called by muse, mutect2, varscan2
- DNAH1 | c.6685A>G p.T2229A | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as rs192221185, COSV101324793; called by muse, mutect2, varscan2
- DNAH7 | c.11650T>C p.F3884L | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100413917; called by muse, mutect2, varscan2
- DOCK6 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as rs1381761927, COSV99370876; called by muse, mutect2
- FAM184A | c.2479C>T p.H827Y | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.173); catalogued as COSV100137412; called by muse, mutect2, varscan2
- FBXO17 | c.505G>C p.V169L | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99493947; called by muse, mutect2, varscan2
- FOCAD | c.4843G>T p.V1615L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs376770371, COSV100620074; called by muse, mutect2, varscan2
- FRMPD4 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV101042183; called by muse, mutect2, varscan2
- FSIP2 | c.18899C>T p.P6300L | Missense Mutation (SNP) | VAF 136/313 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as COSV100554095; called by muse, mutect2, varscan2
- FUT10 | c.34T>C p.S12P | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV100161234; called by muse, mutect2, varscan2
- GPAT2 | c.1700G>C p.R567T | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.218); catalogued as COSV64004181; called by muse, mutect2
- GZMK | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as COSV99140836; called by muse, mutect2, varscan2
- HAS1 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99708223; called by muse, mutect2, varscan2
- HAVCR1 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1196575610, COSV59399348; called by muse, mutect2, varscan2
- HGD | c.255G>T p.W85C | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV52200978, COSV99380683; called by muse, mutect2, varscan2
- HMBS | c.912+2T>C p.X304_splice | Splice Site (SNP) | VAF 59/126 reads (47%) | catalogued as CS104064, COSV99597815; called by muse, mutect2, varscan2
- KCTD8 | c.911A>G p.Q304R | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs1406831947, COSV100759162; called by muse, mutect2, varscan2
- KIT | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99853357; called by muse, mutect2, varscan2
- MEGF9 | c.1141C>G p.P381A | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.096); catalogued as COSV100879315; called by muse, mutect2, varscan2
- MIB1 | c.2401G>T p.V801L | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.355); catalogued as COSV99838387; called by muse, mutect2, varscan2
- MICAL2 | c.3290C>G p.S1097C | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV56317872, COSV99816758; called by muse, mutect2, varscan2
- MRPS30 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV101539262; called by muse, mutect2, varscan2
- PLD5 | c.1064C>A p.T355N (on ENST00000442594; = p.T293N on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/158 reads (58%) | SIFT tolerated (0.55); PolyPhen benign (0.035); catalogued as COSV100138889; called by muse, mutect2, varscan2
- POLQ | c.485A>G p.Q162R | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV99951671; called by muse, mutect2, varscan2
- PSMG1 | c.489G>C p.Q163H | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV100521858; called by muse, mutect2, varscan2
- RB1CC1 | c.1689+1G>A p.X563_splice | Splice Site (SNP) | VAF 194/278 reads (70%) | catalogued as COSV50252907; called by muse, mutect2, varscan2
- REL | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 151/394 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs752907267, COSV99691853; called by muse, mutect2, varscan2
- RET | c.1761G>A p.R587= | Splice Region (SNP) | VAF 17/32 reads (53%) | catalogued as rs1291641320, COSV60690988; called by muse, mutect2, varscan2
- SCUBE1 | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747699067, COSV51809335; called by muse, mutect2, varscan2
- SIGIRR | c.853T>A p.L285M | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV100229817; called by muse, mutect2, varscan2
- SPATA5L1 | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99972841; called by muse, mutect2, varscan2
- STRBP | c.968A>G p.Y323C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV100724092; called by muse, mutect2, varscan2
- SVEP1 | c.1816C>A p.H606N | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.054); catalogued as COSV100237274; called by muse, mutect2, varscan2
- TADA2B | c.761A>G p.E254G | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99380552; called by muse, mutect2, varscan2
- TLN2 | c.5435T>C p.M1812T | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs1344287500, COSV100168079; called by muse, mutect2, varscan2
- TOR1B | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.06); catalogued as COSV99399990; called by muse, mutect2, varscan2
- TPRX1 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.872); catalogued as rs147380237; called by muse, varscan2
- TRPC4 | c.2698C>A p.P900T (on ENST00000379705 / NM_016179.4; = p.P905T on NM_003306.3) | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.011); catalogued as COSV100155968; called by muse, mutect2, varscan2
- TSHZ3 | c.168C>G p.C56W | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.405); catalogued as COSV99550694; called by muse, mutect2, varscan2
- XYLT1 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99760405, COSV99762006; called by muse, mutect2, varscan2
- ZNF227 | c.1352T>G p.L451* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV100480234; called by muse, mutect2, varscan2
- ZNF382 | c.814A>G p.K272E | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs764236830, COSV99497479; called by muse, mutect2, varscan2
- ZNF569 | c.843G>T p.Q281H | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.99); catalogued as COSV100386343; called by muse, mutect2, varscan2
- ZNF813 | c.1736A>T p.Y579F | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.84); catalogued as COSV101124689; called by muse, mutect2, varscan2
- STXBP2 | c.1186_1192del p.A396Cfs*20 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.5937G>A p.V1979= | Silent (SNP) | VAF 20/25 reads (80%) | catalogued as COSV99782163; called by muse, mutect2, varscan2
- ATRX | c.2028T>C p.N676= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV100970119; called by muse, mutect2, varscan2
- B4GALT4 | c.240G>A p.V80= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs761517196, COSV100785759; called by muse, mutect2, varscan2
- COLEC12 | c.1734C>A p.G578= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as rs762468517, COSV101231959, COSV68370778; called by muse, mutect2
- GALNT13 | c.1467A>G p.G489= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as COSV101222248; called by muse, mutect2, varscan2
- GOLGA4 | c.934T>C p.L312= | Silent (SNP) | VAF 163/421 reads (39%) | catalogued as COSV100728664; called by muse, mutect2, varscan2
- HCN4 | c.183C>T p.A61= | Silent (SNP) | VAF 139/295 reads (47%) | catalogued as COSV99983321; called by muse, mutect2, varscan2
- HHIP | c.762T>C p.L254= | Silent (SNP) | VAF 63/159 reads (40%) | catalogued as COSV99666643; called by muse, mutect2, varscan2
- OSMR | c.1749C>T p.S583= | Silent (SNP) | VAF 73/151 reads (48%) | catalogued as COSV57086097; called by muse, mutect2, varscan2
- PLEKHO1 | c.963G>A p.E321= | Silent (SNP) | VAF 16/308 reads (5%) | catalogued as COSV99215119; called by muse, mutect2
- QRFPR | c.94C>A p.R32= | Silent (SNP) | VAF 72/169 reads (43%) | catalogued as COSV100543476, COSV57679295; called by muse, mutect2, varscan2
- TAGAP | c.1593G>A p.S531= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100487276; called by muse, mutect2, varscan2
- TIAL1 | c.432T>G p.S144= | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as rs1385869737, COSV100958332; called by muse, mutect2, varscan2
- TRIM14 | c.1158C>T p.D386= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs1409005229, COSV99271088; called by muse, mutect2, varscan2
- TRIP13 | c.990C>T p.I330= | Silent (SNP) | VAF 25/187 reads (13%) | catalogued as COSV99386216; called by muse, varscan2
- ZNF223 | c.708A>G p.Q236= | Silent (SNP) | VAF 44/91 reads (48%) | catalogued as rs1177275215, COSV71572012; called by muse, mutect2, varscan2
- MIR124-2 | n.80C>T | RNA (SNP) | VAF 34/136 reads (25%) | called by muse, mutect2, varscan2
- SLC4A4 | c.254-65C>T | Intron (SNP) | VAF 57/145 reads (39%) | catalogued as COSV99138996; called by muse, mutect2, varscan2
